Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADG, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADG-01A (Primary Tumor).

[page 1 of 2]
Primary

ICD-O-3

Carcinoma, hepatocellular NOS 8170/3

Site: Liver C22.0

JW 5/19/14

CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Right hemihepatectomy

Cholecystectomy

Organs:

[1] Liver: A segment of liver tissue (16.0 x 13.0 x 6.5 cm and 580.5 gm)

Lesion: Two well-defined masses

Size: 7.0 x 6.0 x 5.0 cm (segment 6, 7, and 8) and 2.0 x 1.5 x 1.5 cm
(segment 6)

Cut surface: Yellowish tan, and granular with necrosis (30 %)

Gross type:

HCC: Multinodular confluent

Resection margin: Not involved grossly (safety margin: 1.5 cm)

Remaining parenchyma: Cirrhotic

[2] Gallbladder: 11.0 cm in length, 4.5 cm in diameter, 0.2 cm in wall thickness

Mucosal surface: Green and velvety/ diffusely necrotic mucosa (no stone)

Serosal surface: Brown and smooth

[3] Labeled as 'parasite' (three pieces, 0.8 x 0.6 x 0.3 cm, entirely submitted)

Representative sections are submitted

Gross photo: Present

Blocks

T1-3 and TB, larger mass and surrounding liver parenchyma x 4

T4, smaller mass and surrounding liver parenchyma x 1

L and NB, nontumorous liver parenchyma x 2

RM, resection margin of liver x 1

A, labeled as 'parasite' x 1

GB, gallbladder and cystic duct resection margin x 1

MICROSCOPIC:

[1] Main mass (segment 6, 7, and 8)

Hepatocellular carcinoma:

The worst differentiation III/IV

The major differentiation II/IV

Histologic type: Trabecular

Cell type: Hepatic and clear

Fatty change: No

Fibrous capsule formation: No

Capsular infiltration: No

Septum formation: No

[2] Smaller mass (segment 6)

[page 2 of 2]
Hepatocellular carcinoma:

The worst differentiation III/IV

The major differentiation III/IV

Histologic type: Trabecular

Cell type: Hepatic and clear

Fatty change: No

Fibrous capsule formation: No

Capsular infiltration: No

Septum formation: No

Surgical resection margin invasion: No

Serosal invasion: No

Microvessel invasion: No

Intrahepatic metastasis: No

Multicentric occurrence: Yes

Non-tumor liver pathology

1. Chronic hepatitis:

1-1. Etiology: HBV

1-2. Grade, lobular: Minimal

1-3. Grade, portoperiportal: Mild

1-4. Stage (fibrosis): Septal

2. Dysplastic nodule: No

3. Ductal epithelial dysplasia: No

4. Other liver diseases: Clonorchis sinensis infestation

NOT reported. Gross:

NOT reported. Gross:

Liver, right,ectomy, Hepatocellular carcinoma

T56000, right, P10, M81703

Gallbladder, ectomy, Chronic cholecystitis

T57000, P10, M43005

Tissue labeled as "parasite", biopsy, Clonorchis sinensis infestation

Tissue labeled as "parasite", P50, Clonorchis sinensis infestation

DIAGNOSIS:

Liver, right hemihepatectomy: Hepatocellular carcinoma

Gallbladder, cholecystectomy: Chronic cholecystitis

Tissue labeled as "parasite", biopsy: Clonorchis sinensis infestation

Suggestion :

Source: NCI Genomic Data Commons file 13709736-39d1-4f12-94ec-0888fdc30f9f (TCGA-DD-AADG.E6130559-E3EA-4010-9031-071D55816383.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).